Somatic mutation profile of tumor specimen ALCH-ACGZ-TTP1-A (aliquot ALCH-ACGZ-TTP1-A-2-0-D-A501-36) from ALCHEMIST case ALCH-ACGZ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 38.5 years (14,067 days).
Specimen ALCH-ACGZ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 933f2b45-7544-420a-bb74-d7cf04ceb1cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ACGZ-NB1-A (Blood Derived Normal), aliquot ALCH-ACGZ-NB1-A-1-0-D-A501-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/85e2ab45-3753-4ad4-a31e-bcf07ee763c4

The open-access MAF lists 20 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 4, Intron 2, Splice Site 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCD1 | c.1201C>T p.R401W | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs727503786, CM122938, CM993106, COSV54387385; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNE | c.890G>A p.R297Q (on ENST00000396594 / NM_001128227.3; = p.R266Q on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/510 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs121908622, CM991260, COSV64952287; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DEAF1 | c.69_98del p.A24_A33del | In Frame Del (DEL) | VAF 8/25 reads (32%) | catalogued as rs754135731; called by mutect2, varscan2*
- UBAP1L | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as rs533895547; called by muse, mutect2, varscan2
- ARHGAP45 | c.1485C>G p.I495M | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, varscan2
- ARPP21 | c.364G>T p.D122Y | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- EPHB4 | c.2278G>C p.G760R | Missense Mutation (SNP) | VAF 12/354 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCCB | c.215T>G p.L72R | Missense Mutation (SNP) | VAF 28/406 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- PKD1L1 | c.205G>T p.G69C | Missense Mutation (SNP) | VAF 35/268 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- POLR2B | c.357-2A>T p.X119_splice | Splice Site (SNP) | VAF 15/125 reads (12%) | called by muse, mutect2, varscan2
- PPP1R3A | c.1057G>T p.A353S | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.014); called by muse, mutect2
- SUFU | c.235A>G p.S79G | Missense Mutation (SNP) | VAF 16/460 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2
- TPM1 | c.652G>T p.E218* | Nonsense Mutation (SNP) | VAF 20/454 reads (4%) | called by muse, mutect2
- ZNF568 | c.883A>G p.R295G | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.854); called by muse, mutect2
- DACH1 | c.1290A>G p.E430= (on ENST00000619232 / NM_001366712.1; = p.E378= on NM_080759.6) | Silent (SNP) | VAF 5/82 reads (6%) | called by muse, mutect2
- ECT2L | c.249C>T p.R83= | Silent (SNP) | VAF 10/138 reads (7%) | catalogued as COSV62887717; called by muse, mutect2
- NACC2 | c.762G>C p.L254= | Silent (SNP) | VAF 4/72 reads (6%) | called by muse, mutect2
- RNF123 | c.2562C>T p.R854= | Silent (SNP) | VAF 16/302 reads (5%) | called by muse, mutect2
- IDS | c.418+87C>A | Intron (SNP) | VAF 12/180 reads (7%) | called by muse, mutect2
- SLIRP | c.98-243C>T | Intron (SNP) | VAF 20/140 reads (14%) | catalogued as rs754984721; called by muse, mutect2, varscan2
